Somatic mutation profile of tumor specimen TCGA-71-8520-01A (aliquot TCGA-71-8520-01A-11D-2393-08) from TCGA case TCGA-71-8520, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.0 years (21,921 days).
Specimen TCGA-71-8520-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a9a3cf4-4c75-4c90-beac-eccefc9690da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-71-8520-10A (Blood Derived Normal), aliquot TCGA-71-8520-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d2b3e1f-f8d0-4188-b3bf-7f2ea01620e3

The open-access MAF lists 96 somatic variants for this specimen: 73 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 21, Nonsense Mutation 5, Splice Site 3, Frame Shift Ins 1, RNA 1, Frame Shift Del 1, Splice Region 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.185T>G p.L62R | Missense Mutation (SNP) | VAF 92/185 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV51765770; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 105/199 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- SPG11 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as rs312262711, CM092527, COSV99967971; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.393del p.N131Kfs*39 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs1567554408, COSV52891063, COSV52938317, COSV53696738, COSV53770947; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACOX2 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs145801962; called by muse, mutect2, varscan2
- ADAMTS14 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs373853037, COSV100941843; called by muse, mutect2
- ADRA1B | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs748303035, COSV100140053; called by muse, mutect2, varscan2
- ALMS1 | c.8328G>A p.M2776I | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs775982049, COSV100040998; called by muse, mutect2, varscan2
- ANKRD24 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.021); catalogued as rs1398824043, COSV99516895; called by muse, mutect2
- BEST2 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs367897325, COSV50370803; called by muse, mutect2, varscan2
- BIRC6 | c.3782C>A p.S1261* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV101427789; called by muse, mutect2, varscan2
- CATSPERE | c.2464C>A p.P822T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as COSV100834878; called by muse, mutect2, varscan2
- CCDC81 | c.1816C>T p.R606W (on ENST00000445632 / NM_001156474.2; = p.R516W on NM_021827.4) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138508969; called by muse, mutect2, varscan2
- CLEC4F | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV55479470; called by muse, mutect2, varscan2
- CLTC | c.944T>G p.I315R | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99291636; called by muse, mutect2, varscan2
- COL14A1 | c.3877C>T p.R1293W | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1156568233, COSV52852153; called by muse, mutect2
- CRISPLD2 | c.399C>G p.D133E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as rs146382941, COSV99295338; called by muse, mutect2, varscan2
- DDX27 | c.1307G>T p.R436L | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100873101, COSV65610745; called by muse, mutect2, varscan2
- DNAI3 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV99641282; called by muse, mutect2, varscan2
- DRAXIN | c.429G>T p.R143S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.127); catalogued as COSV99610535; called by muse, mutect2
- DRG2 | c.65-1G>A p.X22_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99854779; called by muse, mutect2, varscan2
- DSCAML1 | c.518G>A p.R173Q (on ENST00000321322; = p.R113Q on NM_020693.4) | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100354431; called by muse, mutect2, varscan2
- ERG | c.926G>A p.R309H (on ENST00000398919 / NM_001243428.1; = p.R285H on NM_004449.4) | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs774038422, COSV55736507; called by muse, mutect2, varscan2
- EZH2 | c.155G>T p.R52I | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV100234640, COSV100236057; called by muse, mutect2, varscan2
- FER1L6 | c.4748G>T p.G1583V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV101205391; called by muse, mutect2, varscan2
- FMN2 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs747413802, COSV100146867, COSV60447753; called by muse, mutect2, varscan2
- GCC2 | c.652C>G p.Q218E | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100565230; called by muse, mutect2, varscan2
- GPR156 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100251086; called by muse, mutect2, varscan2
- GRIN2A | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs560057284, COSV58020945, COSV58030818; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- GRIN2B | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.153); catalogued as COSV101662894; called by muse, mutect2, varscan2
- GTF2IRD1 | c.265+1G>T p.X89_splice | Splice Site (SNP) | VAF 12/94 reads (13%) | catalogued as COSV56092740, COSV99733963; called by muse, mutect2, varscan2
- GYPB | c.48C>A p.S16R | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); catalogued as COSV99300912; called by muse, mutect2
- HNF1B | c.1338A>G p.Q446= | Splice Region (SNP) | VAF 28/155 reads (18%) | catalogued as rs776536485; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HRNR | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs753630791, COSV100912865; called by muse, mutect2, varscan2
- HYOU1 | c.2763G>T p.K921N | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV101345538; called by muse, mutect2, varscan2
- IBSP | c.545A>G p.N182S | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs914479640, COSV99883357; called by muse, mutect2, varscan2
- KCNH1 | c.1471T>C p.Y491H (on ENST00000271751 / NM_172362.3; = p.Y464H on NM_002238.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99657080; called by muse, mutect2, varscan2
- KCTD5 | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100069443, COSV100069710; called by muse, mutect2, varscan2
- KIF1C | c.976A>T p.S326C | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100296932; called by muse, mutect2, varscan2
- LRRTM4 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69141662; called by muse, mutect2, varscan2
- LTA4H | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV99956876; called by muse, mutect2, varscan2
- LUZP2 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61219906; called by muse, mutect2, varscan2
- MDGA2 | c.2313T>A p.Y771* (on ENST00000399232 / NM_001113498.2; = p.Y473* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100636293; called by muse, mutect2, varscan2
- MGA | c.1551G>T p.E517D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV99578315; called by muse, mutect2, varscan2
- MPO | c.1600T>C p.S534P | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.836); catalogued as COSV99228297; called by muse, mutect2, varscan2
- MS4A4A | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV100557699, COSV59703940; called by muse, mutect2, varscan2
- NCOR2 | c.4309C>T p.P1437S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100656763; called by muse, mutect2, varscan2
- PCDHA9 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 51/366 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV100968960; called by muse, mutect2, varscan2
- PIK3R5 | c.1296C>G p.S432R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.583); catalogued as COSV99352828; called by muse, mutect2, varscan2
- PMM2 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as rs778549166, COSV99191101; called by muse, mutect2, varscan2
- PRICKLE2 | c.2024G>A p.G675E (on ENST00000295902; = p.G619E on NM_198859.4) | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV55766339; called by muse, mutect2, varscan2
- RECQL | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100131139, COSV59086181; called by muse, mutect2, varscan2
- RYR1 | c.7208G>A p.R2403H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs749136416, COSV62087171; called by muse, mutect2, varscan2
- RYR2 | c.4210A>G p.R1404G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100767546, COSV100769155; called by muse, mutect2, varscan2
- SCN10A | c.4513A>C p.T1505P | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV101479223; called by muse, mutect2, varscan2
- SLC17A8 | c.1659G>T p.Q553H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100035137; called by muse, mutect2, varscan2
- SLC9A1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99849243; called by muse, mutect2, varscan2
- SORCS3 | c.1892G>A p.R631K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.047); catalogued as COSV100864427; called by muse, mutect2, varscan2
- TEPSIN | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100329502; called by muse, mutect2, varscan2
- TRIM5 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as COSV99999943; called by muse, mutect2, varscan2
- TUBGCP6 | c.2068C>T p.R690W | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774338870, COSV50541673; called by muse, varscan2
- UBE2Z | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100711463; called by muse, mutect2, varscan2
- UGT2A1 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs1239729672, COSV54139038; called by muse, mutect2, varscan2
- USP9X | c.3986G>A p.R1329H | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391287100, COSV100198402; called by muse, mutect2, varscan2
- VEGFD | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs759239709, COSV99938251; called by muse, mutect2, varscan2
- WEE2 | c.261C>A p.H87Q | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV101285110; called by muse, mutect2
- ZFYVE16 | c.3512C>A p.P1171H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561302787, COSV100566165; called by muse, mutect2, varscan2
- ZNF383 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV100776730; called by muse, mutect2, varscan2
- ZNF385D | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99873130; called by muse, mutect2, varscan2
- ZNF581 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as COSV99553022; called by muse, mutect2, varscan2
- MAP3K14 | c.1561_1566del p.V521_L522del | In Frame Del (DEL) | VAF 12/41 reads (29%) | called by mutect2, pindel, varscan2
- RUVBL1 | c.594_603+4del p.X198_splice | Splice Site (DEL) | VAF 62/310 reads (20%) | called by mutect2, pindel, varscan2
- SLC4A8 | c.2108dup p.T704Hfs*13 | Frame Shift Ins (INS) | VAF 51/127 reads (40%) | called by mutect2, pindel, varscan2
- ALLC | c.726G>A p.R242= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV99377412; called by muse, mutect2, varscan2
- CCNB1IP1 | c.315C>G p.L105= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV62302660; called by muse, mutect2, varscan2
- CDCA2 | c.891A>C p.A297= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100398727; called by muse, mutect2, varscan2
- CNTN3 | c.1836A>C p.T612= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99723122; called by muse, mutect2, varscan2
- EPAS1 | c.2481C>T p.L827= | Silent (SNP) | VAF 42/235 reads (18%) | catalogued as rs765104652, COSV99762844; called by muse, mutect2, varscan2
- FANCC | c.1176G>A p.E392= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV100001929; called by muse, mutect2, varscan2
- FLNA | c.5967G>A p.P1989= (on ENST00000369850 / NM_001110556.2; = p.P1981= on NM_001456.3) | Silent (SNP) | VAF 6/164 reads (4%) | catalogued as rs372351673, COSV61043535; ClinVar: likely benign; called by muse, mutect2
- GFI1 | c.1194C>T p.C398= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs1348982767, COSV54043296; called by muse, mutect2, varscan2
- KIF22 | c.1947G>A p.L649= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as COSV99360807; called by muse, mutect2, varscan2
- KIRREL2 | c.2106G>A p.P702= (on ENST00000360202 / NM_199180.4; = p.A613T on NM_032123.7) | Silent (SNP) | VAF 38/202 reads (19%) | catalogued as rs143366792, COSV99383495; called by muse, mutect2, varscan2
- MUC16 | c.38763T>G p.T12921= | Silent (SNP) | VAF 25/183 reads (14%) | catalogued as COSV101197934; called by muse, mutect2, varscan2
- MUC5B | c.11079C>T p.L3693= | Silent (SNP) | VAF 91/298 reads (31%) | catalogued as COSV101499999; called by muse, mutect2, varscan2
- OGDHL | c.528G>A p.P176= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs749032296, COSV65101280; called by muse, varscan2
- PKDREJ | c.1920T>C p.A640= | Silent (SNP) | VAF 17/201 reads (8%) | catalogued as COSV99478378; called by muse, mutect2
- RPGRIP1 | c.2802C>T p.S934= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99250350; called by muse, mutect2, varscan2
- SERGEF | c.1206G>T p.L402= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs1367587268, COSV56381976, COSV99786856; called by muse, mutect2, varscan2
- SLC22A3 | c.1521A>C p.A507= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV99278274; called by muse, mutect2, varscan2
- SMURF2 | c.1512C>T p.F504= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV99300270; called by muse, mutect2, varscan2
- SPATA31D1 | c.1176G>A p.G392= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100782449; called by muse, mutect2, varscan2
- TLX2 | c.408C>G p.L136= | Silent (SNP) | VAF 30/182 reads (16%) | catalogued as COSV99283521; called by muse, mutect2, varscan2
- TPCN1 | c.1281G>A p.A427= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as rs751098184, COSV59234505; called by muse, mutect2, varscan2
- COL6A2 | c.2462-2645G>A | Intron (SNP) | VAF 25/194 reads (13%) | catalogued as COSV100152905; called by muse, mutect2, varscan2
- MIR1297 | n.23A>G | RNA (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
